Gene-level copy-number profile of tumor specimen ALCH-B2UM-TTP1-A from ALCHEMIST case ALCH-B2UM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.2 years (24,164 days).
Specimen ALCH-B2UM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f9ee9b9e-4821-4c7e-af89-49ec2b4facb1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2UM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/b6c4411c-8fdf-4124-97b9-a827884f4f6c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 3,795; copy number 2: 51,922; copy number 3: 2,603; copy number 4: 16; copy number 5: 7; copy number 7: 3; copy number 36: 1.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,362,019–12,414,373, 5 genes: FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3.
- chr11:65,592,836–65,650,918, 6 genes (within-gene range 0–2): KCNK7, MAP3K11, PCNX3, MIR4690, SIPA1, MIR4489.
- chr14:105,486,317–105,499,575, 3 genes: CRIP1, AL928654.3, TEDC1.
- chr15:25,176,832–25,243,695, 37 genes (within-gene range 0–2): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40.
- chr16:56,351,886–56,353,524, 1 gene (within-gene range 0–2): AC009102.2.
- chr16:88,382,959–88,440,757, 1 gene: ZNF469.
- chr22:45,920,366–45,977,162, 1 gene (within-gene range 0–2): WNT7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:219,482,073–219,516,877, 5 genes, copy number 5 (within-gene range 2–5): ASIC4-AS1, AC053503.6, SPEGNB, AC053503.4, GMPPA.
- chr8:12,333,644–12,359,391, 3 genes, copy number 5–7: RNA5SP254, DEFB108E, ZNF705CP.
- chr14:105,472,962–105,480,162, 1 gene, copy number 7: CRIP2.
- chr21:43,053,191–43,076,943, 1 gene, copy number 36: CBS.
- chr21:43,140,523–43,141,092, 1 gene, copy number 7: FRGCA.

Autosomal genes at a single copy (total copy number 1): 1,507. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
